Gene-level copy-number profile of tumor specimen TCGA-DI-A1NO-01A from TCGA case TCGA-DI-A1NO, project TCGA-UCEC (Uterine Corpus Endometrial Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Endometrioid adenocarcinoma, NOS; Tissue or organ of origin: Endometrium; FIGO stage: Stage IIIA; Tumor grade: G3; Age at diagnosis: 68.4 years (24,996 days).
Specimen TCGA-DI-A1NO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-UCEC.3fdbb9cf-afb9-41f3-8963-eef43dafc703.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-DI-A1NO-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 809 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/184a462e-fd54-4692-9c44-9cfda61909b6

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 2,655; copy number 2: 20,078; copy number 3: 21,781; copy number 4: 9,897; copy number 5: 2,613; copy number 6: 442; copy number 7: 1,118; copy number 8: 675; copy number 9: 24; copy number 10: 13; copy number 11: 518.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-DI-A1NO-01A-31D-A160-01): tumor purity 0.94, ploidy 3.01, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 2,348 genes in 15 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:155,845,367–156,299,307, 31 genes, copy number 8: AL139128.1, SYT11, U4, RIT1, KHDC4, SNORA80E, SCARNA4, SCARNA4, RXFP4, ARHGEF2, MIR6738, AL355388.1, ARHGEF2-AS1, AL355388.2, SSR2, UBQLN4, LAMTOR2, RAB25, MEX3A, LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6, SMG5, TMEM79, GLMP, VHLL.
- chr2:164,213,539–164,322,223, 2 genes, copy number 7: PRPS1P1, CYP2C56P.
- chr3:94,506,766–94,507,620, 1 gene, copy number 7: ARMC10P1.
- chr3:138,935,189–175,810,548, 539 genes, copy number 7–11 (within-gene range 5–11) (broad region; genes not listed).
- chr3:175,059,361–198,222,513, 497 genes, copy number 7 (broad region; genes not listed).
- chr5:7,396,138–41,261,438, 486 genes, copy number 8–11 (within-gene range 5–11) (broad region; genes not listed).
- chr6:13,264,861–31,278,754, 554 genes, copy number 7 (broad region; genes not listed).
- chr9:129,321,016–129,636,135, 13 genes, copy number 7 (within-gene range 5–7): C9orf106, AL353803.5, LINC01503, RN7SL159P, AL353803.3, AL353803.2, AL353803.1, LINC00963, AL353803.4, AL391056.2, AL391056.1, NTMT1, C9orf50.
- chr10:50,736,078–50,885,675, 4 genes, copy number 8: AL589794.2, ASAH2B, A1CF, AL512366.1.
- chr14:55,651,534–55,796,731, 4 genes, copy number 8: Y_RNA, AL355773.1, RPL13AP3, LINC00520.
- chr18:26,226,445–26,391,685, 1 gene, copy number 8 (within-gene range 5–8): TAF4B.
- chr18:26,348,347–26,438,041, 3 genes, copy number 8: AC022069.1, RNU6-1289P, LINC01543.
- chr20:87,250–5,197,887, 163 genes, copy number 11 (broad region; genes not listed).
- chr20:61,953,469–62,065,810, 1 gene, copy number 7 (within-gene range 5–7): TAF4.
- chr20:62,037,429–62,937,952, 49 genes, copy number 7 (within-gene range 5–7): AL137077.1, MIR3195, AL137077.2, LSM14B, PSMA7, SS18L1, MTG2, HRH3, OSBPL2, ADRM1, AL354836.1, LAMA5, MIR4758, LAMA5-AS1, AL121832.2, RPS21, CABLES2, AL121832.3, RBBP8NL, AL121832.1, GATA5, AL499627.2, AL499627.1, MIR1-1HG-AS1, MIR1-1HG, MIR1-1, MIR133A2, RPL7P3, BX640514.1, BX640514.2, AL450469.2, AL450469.1, AL357033.1, SLCO4A1, AL357033.4, AL357033.3, SLCO4A1-AS1, LINC00686, NTSR1, AL357033.2, LINC00659, MRGBP, OGFR-AS1, OGFR, COL9A3, TCFL5, DPH3P1, ARF4P2, DIDO1.

Autosomal genes at a single copy (total copy number 1): 2,642. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
